Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4177, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4177-01A (Primary Tumor).

[page 1 of 2]
Clinical Diagnosis & History:

Patient with right renal mass.

Specimens Submitted:

1: Kidney, right, perinephric "fat", partial nephrectomy

DIAGNOSIS:

1. Kidney, right, perinephric "fat", partial nephrectomy

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade II/IV

Tumor Size:

Greatest diameter is 2.5 cm.

Local Invasion (for renal cortical types):

Not Identified

Renal Vein Invasion:

NA

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Focal myoid metaplasia

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

Comment: Unremarkable perinephric adipose tissue

[page 2 of 2]
Gross Description:

1). The specimen is received initially fresh, and later in formalin, after having been inked black and breadloafed for retrieval of tissue for TPS, labeled, "Right partial nephrectomy and perinephric fat", and consists of a portion of red-tan kidney parenchyma measuring 4.5 x 3.5 x 2.3 cm upon reconstruction of the specimen. It shows a 2.5 x 2.5 x 2.2 centimeter well circumscribed somewhat lobulated yellow-tan tumor. It is located 0.1 cm from the black inked margin. The remainder of the parenchyma is red-tan and grossly unremarkable. What appears to be the capsule of the kidney is inked blue. The tumor grossly abuts this blue inked surface. Also received in the container is an unoriented piece of yellow-tan fatty tissue measuring 6 x 5 x 1.2 cm. cut sections the tissue is grossly unremarkable. Representative sections are submitted.

Summary of sections:

T-representative sections of tumor with black inked margin and capsule

RS-representative section of uninvolved kidney parenchyma

FAT -- fat

Summary of Sections:

Part 1: Kidney, right, perinephric "fat", partial nephrectomy

Block	Sect. Site	PCs
1	fat	1
1	rs	1
4	t	4

Source: NCI Genomic Data Commons file 248b97b1-3beb-48e1-8784-ea9c909b35f2 (TCGA-BP-4177.3C05BD94-B06A-49A4-85D0-8B6B8831883F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).